Somatic mutation profile of tumor specimen C3L-02746-01 (aliquot CPT0188270007) from CPTAC case C3L-02746, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.6 years (24,310 days).
Specimen C3L-02746-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07ac3a99-33f0-4f52-ab94-4147f3833507.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02746-31 (Blood Derived Normal), aliquot CPT0183130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de87ba31-212b-4ece-8f2d-400acd5838c7

The open-access MAF lists 97 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Nonsense Mutation 7, 3'UTR 3, Intron 3, In Frame Del 3, In Frame Ins 2, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1633C>T p.L545F (on ENST00000288602 / NM_001374244.1; = p.L505F on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/354 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs397507477; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 95/282 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.605C>G p.S202W | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs369659108, COSV99392936; called by muse, mutect2, varscan2
- APPBP2 | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1428462551; called by muse, mutect2, varscan2
- ASB15 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778047017, COSV51926047; called by muse, mutect2, varscan2
- ATP9B | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 54/150 reads (36%) | catalogued as rs775938694; called by muse, mutect2, varscan2
- CENPC | c.464C>A p.S155Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99893566; called by muse, mutect2
- CEP290 | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049569883; called by muse, mutect2, varscan2
- CHRND | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs149439815, COSV51317664, COSV51323612; called by muse, mutect2, varscan2
- CSMD2 | c.3859G>A p.G1287R | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs973556782, COSV53911521; called by muse, mutect2, varscan2
- CTCF | c.1837+1G>T p.X613_splice | Splice Site (SNP) | VAF 37/46 reads (80%) | catalogued as COSV50530714; called by muse, mutect2, varscan2
- CYP4V2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs770048736; called by muse, mutect2, varscan2
- DDX60L | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776813390, COSV99487479, COSV99487904; called by muse, mutect2, varscan2
- DOC2A | c.619_621del p.K207del | In Frame Del (DEL) | VAF 76/266 reads (29%) | catalogued as rs1051175353; called by pindel, varscan2
- DRC7 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 87/137 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs760016283; called by muse, mutect2, varscan2
- GRM2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs755306821, COSV56586861; called by muse, mutect2
- GUCY2D | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV99644057; called by muse, mutect2, varscan2
- GYS2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 105/320 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs114025396, COSV99680100; called by muse, mutect2, varscan2
- KIAA1549L | c.2432C>T p.T811M (on ENST00000321505; = p.T1108M on NM_012194.3) | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs774799305, COSV99683151; called by muse, mutect2, varscan2
- MGA | c.7306C>T p.R2436C (on ENST00000219905 / NM_001164273.1; = p.R2227C on NM_001080541.2) | Missense Mutation (SNP) | VAF 168/496 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54957604, COSV54963876; called by muse, mutect2, varscan2
- NPL | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs780412696, COSV51122580; called by muse, mutect2, varscan2
- NSL1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 100/312 reads (32%) | catalogued as COSV100875296; called by muse, mutect2, varscan2
- OR4D2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 183/591 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs370339516; called by muse, mutect2, varscan2
- PCDH17 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV64971804; called by muse, mutect2, varscan2
- PCDHA13 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 115/291 reads (40%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.282); catalogued as rs781811851, COSV56480759; called by muse, mutect2, varscan2
- PHF3 | c.4451C>T p.A1484V | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1286251187; called by muse, mutect2, varscan2
- PLEKHG5 | c.185G>A p.R62Q (on ENST00000400915 / NM_001042663.3; = p.R25Q on NM_020631.6) | Missense Mutation (SNP) | VAF 18/639 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1201574261, COSV61702728, COSV61704620; called by muse, mutect2
- RAB40C | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as rs757405774, COSV50194293; called by muse, mutect2, varscan2
- RAP1GAP2 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs868571850, COSV54582792; called by muse, mutect2, varscan2
- RDH16 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 115/401 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as rs769936511; called by muse, mutect2, varscan2
- SAGE1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.293); catalogued as rs1419898429, COSV61013051; called by muse, mutect2, varscan2
- SIGLEC1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 124/367 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs200482262, COSV52474640; called by muse, mutect2, varscan2
- SLC44A5 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs373084017; called by muse, mutect2, varscan2
- SLC9A2 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs772980419, COSV52135881; called by muse, mutect2, varscan2
- SLITRK3 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as rs1478735221, COSV53848453; called by muse, mutect2, varscan2
- ZNF275 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs781856747, COSV64704923; called by muse, mutect2, varscan2
- ZNF621 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 135/423 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as rs144763141; called by muse, mutect2, varscan2
- ACTB | c.1090_1101dup p.E364_P367dup | In Frame Ins (INS) | VAF 106/483 reads (22%) | called by mutect2, varscan2
- AVPR1A | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- BRD1 | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- CCDC144A | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CSK | c.40_45dup p.C14_I15dup | In Frame Ins (INS) | VAF 64/411 reads (16%) | called by mutect2, pindel, varscan2
- DSCAM | c.4029C>A p.S1343R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAM114A2 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- GPR82 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- IDO2 | c.304C>T p.Q102* (on ENST00000389060; = p.Q115* on NM_194294.2) | Nonsense Mutation (SNP) | VAF 93/286 reads (33%) | called by muse, mutect2, varscan2
- KLK1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- MARCHF4 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- METTL14 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MUC4 | c.11655C>A p.D3885E | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.428); called by muse, varscan2
- NLRP14 | c.282_283del p.E94Dfs*12 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by pindel, varscan2
- OR10G2 | c.826dup p.A276Gfs*39 | Frame Shift Ins (INS) | VAF 56/206 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGA11 | c.2025C>A p.D675E | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- POLRMT | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- PPP1R3A | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PRR23B | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PTEN | c.593_600del p.M198Rfs*42 | Frame Shift Del (DEL) | VAF 136/212 reads (64%) | called by mutect2, pindel, varscan2
- RABGGTA | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- RPL5 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SMARCA1 | c.1934T>A p.I645N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SYBU | c.1032_1040del p.M344_S347delinsI (on ENST00000276646 / NM_001099754.2; = p.M343_S346delinsI on NM_017786.6) | In Frame Del (DEL) | VAF 96/302 reads (32%) | called by mutect2, pindel, varscan2
- VGF | c.1787G>C p.R596P | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ZKSCAN7 | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF334 | c.1483_1485del p.G495del | In Frame Del (DEL) | VAF 60/172 reads (35%) | called by mutect2, pindel, varscan2
- ZNF471 | c.1765C>A p.H589N | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF775 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 155/538 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAMTS2 | c.1278C>T p.G426= | Silent (SNP) | VAF 84/342 reads (25%) | catalogued as rs746088783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMC6 | c.354C>T p.C118= (on ENST00000392336; = p.C93= on NM_033415.4) | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs149026162; called by muse, mutect2, varscan2
- CCL4 | c.180G>A p.Q60= | Silent (SNP) | VAF 94/300 reads (31%) | called by muse, mutect2, varscan2
- CDH4 | c.915C>T p.D305= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as rs147617244; called by muse, mutect2, varscan2
- CDH6 | c.1572G>A p.S524= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as rs756761364; called by muse, mutect2, varscan2
- COL18A1 | c.2070C>T p.P690= (on ENST00000359759 / NM_130444.3; = p.P455= on NM_030582.4) | Silent (SNP) | VAF 120/290 reads (41%) | catalogued as rs750922241, COSV100700415; called by muse, mutect2, varscan2
- DLL4 | c.1683C>T p.D561= | Silent (SNP) | VAF 122/337 reads (36%) | catalogued as rs1485634385; called by muse, mutect2, varscan2
- FLNA | c.3739C>T p.L1247= | Silent (SNP) | VAF 78/205 reads (38%) | called by muse, mutect2, varscan2
- GPC5 | c.1174C>A p.R392= | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- LMAN1L | c.936G>A p.T312= | Silent (SNP) | VAF 62/198 reads (31%) | catalogued as rs753358635; called by muse, mutect2, varscan2
- MRPL4 | c.354C>T p.A118= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs560148153; called by muse, mutect2, varscan2
- NFATC1 | c.2601G>A p.A867= (on ENST00000427363 / NM_001278669.2; = p.A854= on NM_172387.3) | Silent (SNP) | VAF 47/147 reads (32%) | catalogued as rs368703221; called by muse, mutect2, varscan2
- NTN5 | c.327C>T p.P109= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs746359958, COSV54309043; called by muse, mutect2, varscan2
- PPOX | c.780C>T p.L260= | Silent (SNP) | VAF 114/334 reads (34%) | called by muse, mutect2, varscan2
- PTPRM | c.1908G>A p.T636= | Silent (SNP) | VAF 78/254 reads (31%) | catalogued as rs776894602, COSV59866967; called by muse, mutect2, varscan2
- RASIP1 | c.639G>A p.A213= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as rs1053622854; called by muse, mutect2, varscan2
- RPTOR | c.1875G>A p.T625= | Silent (SNP) | VAF 17/292 reads (6%) | catalogued as rs568041306; called by muse, mutect2
- SDK2 | c.1653C>T p.N551= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as rs1461173741, COSV66191639; called by muse, mutect2
- SWSAP1 | c.120G>A p.L40= (on ENST00000312423; = p.L61= on NM_175871.4) | Silent (SNP) | VAF 104/464 reads (22%) | called by muse, mutect2, varscan2
- TEP1 | c.3378C>T p.D1126= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as rs368221574; called by muse, mutect2, varscan2
- TMPRSS15 | c.294A>C p.L98= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- ZNF585A | c.843G>A p.Q281= (on ENST00000292841 / NM_001288800.2; = p.Q226= on NM_152655.3) | Silent (SNP) | VAF 67/194 reads (35%) | called by muse, mutect2, varscan2
- BCL2L15 | c.*18C>G | 3'UTR (SNP) | VAF 16/235 reads (7%) | catalogued as COSV63642999; called by muse, mutect2
- BMS1P15 | n.644C>A | RNA (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- COCH | chr14:30894909 A>T | 3'Flank (SNP) | VAF 6/48 reads (13%) | catalogued as rs1317914695, COSV53549614; called by muse, varscan2
- DUSP4 | c.433+4414G>A | Intron (SNP) | VAF 79/273 reads (29%) | called by muse, mutect2, varscan2
- LMTK3 | c.*20C>T | 3'UTR (SNP) | VAF 22/198 reads (11%) | catalogued as rs753159856; called by muse, mutect2, varscan2
- PDLIM3 | c.*28G>C | 3'UTR (SNP) | VAF 68/363 reads (19%) | catalogued as COSV52980221, COSV99507461; called by mutect2, varscan2
- SATB2 | c.1173+77T>C | Intron (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SEMA5B | c.3091+115C>T | Intron (SNP) | VAF 31/108 reads (29%) | catalogued as rs958109560; called by muse, mutect2, varscan2
- SPRR2A | c.-15T>C | 5'UTR (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
